Somatic mutation profile of tumor specimen 25db2586-55b0-4456-9bba-c24e06 (aliquot 25db2586-55b0-4456-9bba-c24e06_D6) from CPTAC case 06BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.0 years (21,169 days).
Specimen 25db2586-55b0-4456-9bba-c24e06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e77e3ef-9529-4d60-a806-14dab6e38ca7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 8d94b162-fa3a-4856-8c84-078f65 (Blood Derived Normal), aliquot 8d94b162-fa3a-4856-8c84-078f65_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fe0a210-7462-4b3b-b13c-f290b3f66c2c

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 2, Intron 1, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIR3DL2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs533558523; called by muse, mutect2
- LYPD8 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 80/672 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1553283056; called by muse, mutect2, varscan2
- ODF2 | c.2467C>T p.R823C (on ENST00000434106 / NM_153433.2; = p.R799C on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs368885613; called by muse, mutect2, varscan2
- RARB | c.247C>T p.R83* (on ENST00000383772 / NM_001290216.2; = p.R76* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV58066006; called by muse, mutect2, varscan2
- SETX | c.5318A>G p.Y1773C | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs772754700; called by muse, mutect2, varscan2
- ADORA1 | c.831_847delinsT p.H278* | Frame Shift Del (DEL) | VAF 33/109 reads (30%) | called by pindel, varscan2*
- CHST9 | c.191T>A p.V64E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIC | c.15dup p.R6Qfs*45 | Frame Shift Ins (INS) | VAF 41/130 reads (32%) | called by pindel, varscan2
- CRNN | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 132/576 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, varscan2
- DCAF6 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DONSON | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCP1 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2K4 | c.344del p.S115Lfs*13 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | called by mutect2, pindel, varscan2
- PABPC4L | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH18 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by mutect2, varscan2
- SERP2 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TACSTD2 | c.648_680del p.D216_F226del | In Frame Del (DEL) | VAF 30/400 reads (8%) | called by mutect2, pindel
- TANC1 | c.4062G>T p.M1354I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCEA2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TMEM161B | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPM4 | c.3104T>A p.L1035Q | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD7 | c.2286C>T p.D762= | Silent (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2
- HEPH | c.177C>T p.S59= (on ENST00000343002; = p.S113= on NM_138737.5) | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- PKDCC | c.894C>T p.D298= | Silent (SNP) | VAF 121/422 reads (29%) | catalogued as rs761404378, COSV54308431; called by muse, mutect2, varscan2
- PLK2 | c.1260C>G p.L420= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- SLC22A2 | c.84G>C p.L28= | Silent (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- CFAP57 | c.1929+81T>A | Intron (SNP) | VAF 69/212 reads (33%) | called by mutect2, varscan2
- CNTN6 | c.-303G>A | 5'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- HERC2P4 | n.457G>T | RNA (SNP) | VAF 181/424 reads (43%) | called by muse, mutect2, varscan2
